Somatic mutation profile of tumor specimen 0D8S56 from CCDI case PBBHMA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.1 years (2,585 days).
Specimen 0D8S56: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c16cbb5f-33ea-46cc-bd5a-e0e1e7de8c0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8S57 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/008aff3b-2a65-4606-baed-3a5601919ae8

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 2, Silent 2, 3'UTR 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 258/602 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DOCK7 | c.4405G>T p.A1469S (on ENST00000635253 / NM_001367561.1; = p.A1438S on NM_033407.3) | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV52020134; called by muse, mutect2, varscan2
- FBXL18 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as rs1216038572; called by muse, mutect2
- KIF4B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 451/950 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753391654, COSV70529106; called by muse, mutect2, varscan2
- KIR2DL3 | c.718A>C p.N240H | Missense Mutation (SNP) | VAF 72/518 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.344); catalogued as COSV60901004; called by muse, varscan2
- LAMA5 | c.10786C>T p.R3596C | Missense Mutation (SNP) | VAF 139/609 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs374679404; called by muse, mutect2, varscan2
- NANOGP8 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 319/733 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.955); catalogued as rs560631713; called by muse, mutect2, varscan2
- NRXN3 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 293/676 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.976); catalogued as rs372128835; called by muse, mutect2, varscan2
- TLN1 | c.6985C>T p.R2329W | Missense Mutation (SNP) | VAF 51/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs117039868; called by muse, varscan2
- ZNF324 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 132/406 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1206579601, COSV52182979; called by muse, mutect2, varscan2
- AMPH | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 90/522 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EBNA1BP2 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 28/650 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2
- GRIN3B | c.1028C>A p.A343D | Missense Mutation (SNP) | VAF 246/551 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NBN | c.1574A>C p.D525A | Missense Mutation (SNP) | VAF 106/637 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SREBF1 | c.3218C>T p.A1073V | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOX | c.955_957del p.K319del | In Frame Del (DEL) | VAF 192/522 reads (37%) | called by pindel, varscan2
- KCNJ4 | c.123C>T p.R41= | Silent (SNP) | VAF 236/522 reads (45%) | called by muse, mutect2, varscan2
- TRPC4 | c.1599C>T p.G533= | Silent (SNP) | VAF 322/666 reads (48%) | catalogued as rs1228722211; called by muse, mutect2, varscan2
- CSGALNACT1 | c.-70G>A | 5'UTR (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2
- CYTH3 | c.712-42C>A | Intron (SNP) | VAF 77/165 reads (47%) | called by muse, mutect2, varscan2
- MGAT5B | c.1849-47C>T | Intron (SNP) | VAF 41/125 reads (33%) | catalogued as rs370699992; called by muse, mutect2, varscan2
- TLR6 | c.*45T>G | 3'UTR (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
